Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A3F5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A3F5-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY RE

Patient
MR #:
DOB/Age/Sex:
YNHH Visit #:
Submitting Physician:

Age: M

Accession #:
Taken:
Accessioned:
Adm-Disch Date:
Reported:

Clinical History and Impression:

Year old male with metastatic melanoma right neck, primary site - back
Increasing shortness of breath, cough, fever 1-2 months
Takes prednisone 30 mg bid, status post Phase I clinical trial with IPL and antiPD1

Specimen(s) Received:
RIGHT NECK CONTENTS

FINAL DIAGNOSIS

LYMPH NOES, RIGHT NECK DISSECTION:

- METASTATIC MELANOMA INVOLVING TWENTY OF FORTY FOUR LYMPH NODES (20/44), SEE NOTE
- EXTRACAPSULAR INVASION IS PRESENT
- JUGULAR VEIN IS FREE OF TUMOR

Note: The largest mass/positive lymph node measures 6.5 cm in greatest dimension and may represent multiple matted lymph nodes.

Pathologist: _____ M.D.
*Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

Received fresh, labeled with the patient's name, unit number, and "right neck contents" is a large resection of soft tissue which measures 13 x 10.5 x 8 cm. On one surface is striated skeletal muscle. The contralateral surface reveals a large nodular mass which measures ~8 cm. A large vein is identified and the specimen is oriented in reference to this vein and skeletal muscle. The specimen is divided into superior, middle, and inferior thirds. The mass occupies ~two-thirds of the specimen and is contained within the superior and middle portions. The specimen is serially sectioned to reveal the aforementioned nodule to measure 6.5 x 6 x 6 cm. Multiple lymph nodes are dissected out. Tissue surrounding the lymph nodes appears fibrous and may represent multiple matted lymph nodes. The primary nodule has a tan-yellow, fleshy, nodular cut surface. The cut surface is uniformly homogenous and grossly does not appear to encase any vessels. Representative sections of the specimen are submitted in 18 cassettes as follows: cassettes 1-3=representative sections

Page 1 of 2

Revised		

105-0-3

Melanoma, NOS 8720/3

Site: lymph node, neck c77.0

lw 11/13/11

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

of dominant nodule, cassettes 4-7=lymph nodes harvested from the superior portion, cassettes 8-10=lymph nodes harvested from the middle portion, cassettes 13-18=lymph nodes harvested from the inferior portion. NOTE: The largest lymph nodes are bisected and a portion submitted in the cassettes. Multiple lymph nodes are in each cassette, starting from 4-18.

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1] RIGHT NECK CONTENTS	18	[Undes]	(18)	(No Description)

Printed by

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file d6f98ba7-67ff-4cd9-9e15-ad1cf90ccfdf (TCGA-DA-A3F5.7F4353B8-A593-4795-BB6A-BBB8C9F2BE9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).